Somatic mutation profile of tumor specimen ALCH-B465-TTP1-A (aliquot ALCH-B465-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B465, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 80.8 years (29,528 days).
Specimen ALCH-B465-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b213ca18-210d-46fd-9c9e-a83e40d7834d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B465-NB1-A (Blood Derived Normal), aliquot ALCH-B465-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c8126d1-3f90-484b-a747-dc6724c0da6f

The open-access MAF lists 96 somatic variants for this specimen: 58 protein-altering or splice-affecting, 20 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 20, Intron 8, Nonsense Mutation 3, 5'Flank 3, 3'UTR 3, 5'UTR 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 30/400 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- ACE | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 40/355 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as rs777657188; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2962C>G p.P988A | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV65888871; called by muse, mutect2
- DAB2IP | c.2669C>T p.A890V (on ENST00000408936; = p.A862V on NM_032552.3) | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.138); catalogued as rs1224354176; called by muse, mutect2
- DNAH5 | c.6107G>T p.R2036L | Missense Mutation (SNP) | VAF 36/494 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54263542; called by muse, mutect2
- ENTPD5 | c.665G>A p.R222K | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV58224471; called by muse, mutect2
- FLG | c.6328A>G p.S2110G | Missense Mutation (SNP) | VAF 32/588 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1310247573; called by muse, mutect2
- GRIP1 | c.868G>T p.D290Y | Missense Mutation (SNP) | VAF 359/783 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54045554; called by muse, mutect2, varscan2
- GRIP1 | c.147G>T p.K49N | Missense Mutation (SNP) | VAF 59/1199 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV54047094; called by muse, mutect2
- HEATR5B | c.1058C>T p.S353F | Missense Mutation (SNP) | VAF 22/402 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV51859721; called by muse, mutect2
- HMCN2 | c.11713G>A p.A3905T | Missense Mutation (SNP) | VAF 14/185 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as rs939397276; called by muse, mutect2
- KCNT2 | c.572C>T p.T191I | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV54090527; called by muse, mutect2, varscan2
- LDB3 | c.253C>A p.R85S | Missense Mutation (SNP) | VAF 31/600 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV53939584; called by muse, mutect2
- LGI1 | c.1505A>G p.Y502C | Missense Mutation (SNP) | VAF 13/192 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101004432; called by muse, mutect2
- NLGN4X | c.2128C>A p.R710S | Missense Mutation (SNP) | VAF 73/532 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs763458960, COSV52016642, COSV52036801; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OTX1 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 44/273 reads (16%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.962); catalogued as rs376661345; called by muse, mutect2, varscan2
- PLOD1 | c.907C>G p.L303V | Missense Mutation (SNP) | VAF 60/779 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs1191265335; called by muse, mutect2
- PORCN | c.985G>T p.A329S (on ENST00000326194 / NM_203475.3; = p.A318S on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/506 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV58226706; called by muse, mutect2
- PRSS12 | c.1180G>A p.G394S | Missense Mutation (SNP) | VAF 26/646 reads (4%) | SIFT tolerated (0.98); PolyPhen benign (0.015); catalogued as rs878974991; called by muse, mutect2
- SALL1 | c.1364C>A p.A455E | Missense Mutation (SNP) | VAF 22/292 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV51764349, COSV99179263; called by muse, mutect2
- SRD5A3 | c.631A>G p.I211V | Missense Mutation (SNP) | VAF 28/466 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs566197351; called by muse, mutect2
- ADH6 | c.128C>A p.A43D | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2
- ASTN2 | c.1359C>A p.S453R (on ENST00000313400 / NM_001365069.1; = p.S402R on NM_014010.5) | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2
- BMP7 | c.52T>C p.W18R | Missense Mutation (SNP) | VAF 31/287 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- BRINP3 | c.1674C>A p.C558* | Nonsense Mutation (SNP) | VAF 29/334 reads (9%) | called by muse, mutect2
- CACNA1F | c.4579C>G p.L1527V | Missense Mutation (SNP) | VAF 45/611 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- CHST3 | c.1187A>T p.Q396L | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- COL6A1 | c.391T>A p.C131S | Missense Mutation (SNP) | VAF 17/543 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CRB1 | c.716G>T p.C239F | Missense Mutation (SNP) | VAF 34/528 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- DRD5 | c.380C>G p.S127C | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ELMOD2 | c.202A>T p.S68C | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.156); called by muse, mutect2
- F11 | c.228T>A p.C76* | Nonsense Mutation (SNP) | VAF 14/188 reads (7%) | called by muse, mutect2
- ICE1 | c.5984G>T p.R1995M | Missense Mutation (SNP) | VAF 20/337 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- JAKMIP1 | c.2359C>A p.L787M | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- KLHDC8A | c.53C>A p.P18H | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.423); called by muse, mutect2
- LRRC7 | c.2453T>C p.V818A (on ENST00000651989 / NM_001370785.2; = p.V785A on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.81); called by muse, mutect2
- MS4A14 | c.1635G>T p.R545S | Missense Mutation (SNP) | VAF 25/350 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.591); called by muse, mutect2
- NID2 | c.1730C>A p.A577D | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- NKX2-4 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 67/734 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NXNL2 | c.231G>T p.Q77H | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- OR10K2 | c.588G>T p.Q196H | Missense Mutation (SNP) | VAF 34/387 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- PABPC1L | c.1076G>T p.G359V | Missense Mutation (SNP) | VAF 60/429 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- PAEP | c.367C>T p.L123F | Missense Mutation (SNP) | VAF 14/436 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.255); called by muse, mutect2
- PDCD1LG2 | c.472G>T p.V158F | Missense Mutation (SNP) | VAF 67/628 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PKHD1 | c.7960G>C p.V2654L | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PREX1 | c.2557C>T p.H853Y | Missense Mutation (SNP) | VAF 13/306 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.021); called by muse, mutect2
- PTPRB | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 296/998 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, varscan2
- RBBP5 | c.1162A>G p.S388G | Missense Mutation (SNP) | VAF 14/372 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- RBMXL2 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.994); called by muse, mutect2
- RTL3 | c.659C>A p.A220E | Missense Mutation (SNP) | VAF 17/474 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2
- SRPK2 | c.1382C>G p.S461C | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.071); called by muse, mutect2
- STOML1 | c.1036G>T p.G346C | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- STRA8 | c.931C>T p.P311S (on ENST00000275764; = p.P289S on NM_182489.2) | Missense Mutation (SNP) | VAF 9/194 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.011); called by muse, mutect2
- TNN | c.3216G>T p.Q1072H | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- TRIM37 | c.1595A>T p.D532V | Missense Mutation (SNP) | VAF 22/452 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); called by muse, mutect2
- TRIM8 | c.533C>A p.S178* | Nonsense Mutation (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- XK | c.307A>C p.I103L | Missense Mutation (SNP) | VAF 30/572 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.454); called by muse, mutect2
- ZNF460 | c.1392T>G p.I464M | Missense Mutation (SNP) | VAF 43/337 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- ADGRL3 | c.1983G>T p.R661= (on ENST00000506720 / NM_001322402.2; = p.R593= on NM_015236.6) | Silent (SNP) | VAF 42/396 reads (11%) | catalogued as COSV63368392; called by muse, mutect2
- AMER3 | c.1716G>A p.P572= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs752442102; called by mutect2, varscan2
- CDC14A | c.1197A>G p.L399= | Silent (SNP) | VAF 10/253 reads (4%) | called by muse, mutect2
- CHST7 | c.1305C>A p.R435= | Silent (SNP) | VAF 18/216 reads (8%) | called by muse, mutect2
- DIO3 | c.630G>A p.T210= | Silent (SNP) | VAF 23/377 reads (6%) | catalogued as rs376385510; called by muse, mutect2
- DLX5 | c.699C>A p.L233= | Silent (SNP) | VAF 14/390 reads (4%) | called by muse, mutect2
- DPP6 | c.675T>A p.P225= (on ENST00000377770 / NM_001364500.2; = p.P163= on NM_001936.5) | Silent (SNP) | VAF 25/186 reads (13%) | called by muse, mutect2, varscan2
- FMNL3 | c.1050G>T p.L350= | Silent (SNP) | VAF 29/253 reads (11%) | called by muse, mutect2, varscan2
- FOXB2 | c.570G>T p.P190= | Silent (SNP) | VAF 42/276 reads (15%) | called by muse, mutect2, varscan2
- KIAA1755 | c.3042C>A p.L1014= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV54081241; called by muse, mutect2, varscan2
- OR11L1 | c.651C>T p.P217= | Silent (SNP) | VAF 45/588 reads (8%) | catalogued as COSV100869484; called by muse, mutect2
- PCDH10 | c.1770G>T p.L590= | Silent (SNP) | VAF 12/153 reads (8%) | called by muse, mutect2
- PCDHB8 | c.1803C>A p.A601= | Silent (SNP) | VAF 26/853 reads (3%) | called by muse, mutect2
- PHACTR4 | c.993C>T p.G331= (on ENST00000373839 / NM_001350159.2; = p.G341= on NM_023923.4) | Silent (SNP) | VAF 12/159 reads (8%) | called by muse, mutect2
- STARD3 | c.1170G>T p.V390= | Silent (SNP) | VAF 38/392 reads (10%) | called by muse, mutect2
- THSD1 | c.375G>T p.V125= | Silent (SNP) | VAF 30/340 reads (9%) | catalogued as COSV51630071, COSV99318848; called by muse, mutect2
- TMCO1 | c.690C>T p.G230= (on ENST00000612311 / NM_001256164.1; = p.G179= on NM_019026.6) | Silent (SNP) | VAF 41/665 reads (6%) | called by muse, mutect2
- UBE2NL | c.192A>T p.P64= | Silent (SNP) | VAF 24/632 reads (4%) | called by muse, mutect2
- WWC1 | c.22C>T p.L8= | Silent (SNP) | VAF 32/196 reads (16%) | called by muse, mutect2, varscan2
- ZMYM4 | c.2619A>T p.A873= | Silent (SNP) | VAF 58/606 reads (10%) | called by muse, mutect2, varscan2
- AL162726.3 | n.255+83137G>T | Intron (SNP) | VAF 96/684 reads (14%) | called by muse, mutect2, varscan2
- AP001893.2 | chr11:126175783 G>A | 3'Flank (SNP) | VAF 44/767 reads (6%) | catalogued as rs916846867; called by muse, mutect2
- DENND1B | c.1350+32T>C | Intron (SNP) | VAF 9/157 reads (6%) | called by muse, mutect2
- FHL2 | chr2:105399503 C>A | 5'Flank (SNP) | VAF 50/626 reads (8%) | catalogued as COSV59078705; called by muse, mutect2
- FHL2 | chr2:105399504 C>A | 5'Flank (SNP) | VAF 50/620 reads (8%) | catalogued as rs917475932; called by muse, mutect2
- FRG2KP | chr16:31569202 A>G | 5'Flank (SNP) | VAF 54/748 reads (7%) | called by muse, mutect2
- GPC3 | c.-14C>A | 5'UTR (SNP) | VAF 12/247 reads (5%) | called by muse, mutect2
- GUK1 | c.154+9G>T | Intron (SNP) | VAF 7/108 reads (6%) | catalogued as rs1268162317; called by muse, mutect2
- IL7R | c.-3A>T | 5'UTR (SNP) | VAF 43/464 reads (9%) | called by muse, mutect2
- LCLAT1 | c.743-33949A>G | Intron (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- MARCHF1 | c.-322-86002C>T | Intron (SNP) | VAF 28/474 reads (6%) | called by muse, mutect2
- NLRX1 | c.*392A>T | 3'UTR (SNP) | VAF 12/408 reads (3%) | called by muse, mutect2
- PA2G4 | c.*942G>C | 3'UTR (SNP) | VAF 14/181 reads (8%) | called by muse, mutect2
- RPS20 | chr8:56069762 T>A | 3'Flank (SNP) | VAF 26/573 reads (5%) | called by muse, mutect2
- SYNGR1 | c.338-63C>T | Intron (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+2139G>T | Intron (SNP) | VAF 24/324 reads (7%) | called by muse, mutect2
- TMPRSS11F | c.1015+1966T>G | Intron (SNP) | VAF 14/240 reads (6%) | called by muse, mutect2
- XIAP | c.*6009C>A | 3'UTR (SNP) | VAF 14/386 reads (4%) | catalogued as rs1183404777; called by muse, mutect2
